Somatic mutation profile of tumor specimen C3L-09184-03 (aliquot CPT0499250006) from CPTAC case C3L-09184, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 54.2 years (19,785 days).
Specimen C3L-09184-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cad754c3-f8cd-46b2-9c87-3c3d23a6ef93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09184-31 (Blood Derived Normal), aliquot CPT0499380002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13d17425-9d24-4446-ac87-c4da11ae2bad

The open-access MAF lists 197 somatic variants for this specimen: 140 protein-altering or splice-affecting, 47 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 125, Silent 47, Intron 7, Nonsense Mutation 6, Frame Shift Del 5, Splice Site 2, 5'UTR 2, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993+1G>C p.X331_splice | Splice Site (SNP) | VAF 127/182 reads (70%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC097636.1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 28/347 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs749884592; called by muse, mutect2
- ACTRT1 | c.1087T>A p.F363I | Missense Mutation (SNP) | VAF 110/274 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100947807, COSV64418960, COSV64419191; called by muse, mutect2, varscan2
- AGBL3 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746148745; called by muse, mutect2
- ATP13A4 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 53/623 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.172); catalogued as rs929598035, COSV55067905; called by muse, mutect2
- BCHE | c.1367T>A p.L456H | Missense Mutation (SNP) | VAF 174/543 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV52257116; called by muse, varscan2
- BRINP1 | c.964T>G p.F322V | Missense Mutation (SNP) | VAF 88/308 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99777270; called by muse, mutect2, varscan2
- CACNA1A | c.5948G>A p.R1983H | Missense Mutation (SNP) | VAF 250/472 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs1057521547, COSV64200989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1C | c.3001C>T p.R1001* | Nonsense Mutation (SNP) | VAF 8/208 reads (4%) | catalogued as rs1555879031, COSV59704596; called by muse, mutect2
- CD1E | c.301T>G p.F101V | Missense Mutation (SNP) | VAF 85/353 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV63771967; called by muse, mutect2, varscan2
- CDH22 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 180/1139 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs1303483268, COSV64837485; called by muse, mutect2, varscan2
- CHAD | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 77/683 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1567862302; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CNTNAP4 | c.2835A>C p.E945D | Missense Mutation (SNP) | VAF 89/371 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56666630; called by muse, mutect2, varscan2
- CPN2 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 133/884 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV100103015; called by muse, mutect2
- CTNND2 | c.1616A>G p.Q539R | Missense Mutation (SNP) | VAF 114/351 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.953); catalogued as rs1561254095; called by muse, mutect2, varscan2
- DDI1 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs778186886, COSV56386828; called by muse, mutect2
- DENND1B | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs140468398; called by muse, mutect2, varscan2
- EMC4 | c.262T>C p.Y88H | Missense Mutation (SNP) | VAF 84/2279 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs1256898544; called by muse, mutect2
- GABRA5 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 71/353 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59482675; called by muse, mutect2, varscan2
- GRIA2 | c.2147A>C p.K716T | Missense Mutation (SNP) | VAF 112/311 reads (36%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV52390467; called by muse, mutect2, varscan2
- HCRTR2 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs200545298, COSV63795564; called by muse, mutect2, varscan2
- KCNQ3 | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 58/766 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1563761224, COSV66464416; called by muse, mutect2
- KIF13B | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 82/341 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1195486165, COSV101580800; called by muse, mutect2, varscan2
- KSR2 | c.2269G>A p.V757I | Missense Mutation (SNP) | VAF 83/316 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.203); catalogued as rs371702381; called by muse, mutect2, varscan2
- MAGEC2 | c.828A>C p.K276N | Missense Mutation (SNP) | VAF 131/409 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV55997644, COSV99909877; called by muse, mutect2, varscan2
- MCTP2 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.101); catalogued as rs143183400; called by muse, mutect2
- MMUT | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 146/576 reads (25%) | SIFT tolerated, low confidence (0.38); PolyPhen probably damaging (0.966); catalogued as rs774766479; called by muse, mutect2, varscan2
- MPIG6B | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 38/735 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1374385431; called by muse, mutect2
- MSR1 | c.478A>C p.S160R | Missense Mutation (SNP) | VAF 88/409 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100027026; called by muse, mutect2, varscan2
- MUC16 | c.38972T>G p.L12991R | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.455); catalogued as COSV67454090; called by muse, mutect2, varscan2
- MUC17 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 101/436 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as COSV60287055; called by muse, mutect2, varscan2
- MYO3A | c.74A>C p.E25A | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56335395, COSV56338667; called by muse, mutect2, varscan2
- MYO9B | c.2104G>A p.G702R | Missense Mutation (SNP) | VAF 132/1284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs368425030; called by muse, mutect2, varscan2
- MYT1 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 101/833 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs367833923; called by muse, mutect2, varscan2
- NLRP3 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs201887896, COSV60228566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOG | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 162/544 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.958); catalogued as rs1208206036; called by muse, mutect2, varscan2
- NTRK3 | c.1660C>A p.L554M | Missense Mutation (SNP) | VAF 97/557 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1170771297, COSV100714072, COSV62307433; called by muse, mutect2, varscan2
- OR51F1 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 103/342 reads (30%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as COSV100598875, COSV58578784; called by muse, mutect2, varscan2
- OR5T3 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 132/423 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195292020, COSV100282927; called by muse, mutect2, varscan2
- OR6P1 | c.582A>C p.Q194H | Missense Mutation (SNP) | VAF 104/457 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV58108666; called by muse, mutect2, varscan2
- OR8D1 | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 123/371 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs749419767, COSV100766621, COSV63441871; called by muse, mutect2, varscan2
- PABPN1L | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 111/435 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.287); catalogued as rs773866701; called by muse, mutect2, varscan2
- PCDHAC1 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 137/379 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781895762, COSV53870678; called by muse, mutect2, varscan2
- PLEK | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 72/292 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.275); catalogued as rs144599110, COSV99310740; called by muse, mutect2, varscan2
- PPFIA4 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 21/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1275968164; called by muse, mutect2
- PRR36 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 26/668 reads (4%) | SIFT tolerated (0.35); catalogued as rs1460778380; called by muse, mutect2
- PTPN22 | c.77A>G p.N26S | Missense Mutation (SNP) | VAF 31/419 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs145473954; called by muse, mutect2
- PTPRF | c.5174G>A p.R1725H | Missense Mutation (SNP) | VAF 89/762 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754926878, COSV63448858; called by muse, mutect2, varscan2
- PTPRQ | c.2161G>A p.A721T (on ENST00000616559; = p.A679T on NM_001145026.2) | Missense Mutation (SNP) | VAF 79/249 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs745470985, COSV57040749; called by muse, mutect2, varscan2
- RIMS1 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 100/371 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV104393423; called by mutect2, varscan2
- RYR3 | c.3512A>C p.N1171T | Missense Mutation (SNP) | VAF 90/1241 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs748477713; called by muse, mutect2
- SALL3 | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 176/397 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1245434668, COSV73306460; called by muse, mutect2, varscan2
- SIX5 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 43/398 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs780320911; called by muse, mutect2, varscan2
- SLC1A7 | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 123/350 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.034); catalogued as rs925138271; called by muse, mutect2, varscan2
- SUPT3H | c.296G>A p.R99H (on ENST00000371460 / NM_181356.3; = p.R88H on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150635035; called by muse, varscan2
- TBX20 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 101/417 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV68782351; called by muse, mutect2, varscan2
- TECPR2 | c.3836A>G p.Q1279R | Missense Mutation (SNP) | VAF 28/589 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.045); catalogued as rs938360182; called by muse, mutect2
- TINAGL1 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 128/389 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as rs755929612, COSV99592943; called by muse, mutect2, varscan2
- TMEM168 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 189/372 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.4); catalogued as rs766315900; called by muse, mutect2, varscan2
- TNKS | c.3944C>T p.A1315V | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs968355257; called by muse, mutect2
- TSPOAP1 | c.2371G>A p.V791M | Missense Mutation (SNP) | VAF 174/614 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs150042045; called by muse, mutect2, varscan2
- UBR5 | c.3769C>T p.R1257C | Missense Mutation (SNP) | VAF 284/462 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs867813343; called by muse, mutect2, varscan2
- USP5 | c.1100C>T p.T367M | Missense Mutation (SNP) | VAF 90/408 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.451); catalogued as rs782311944; called by muse, mutect2, varscan2
- WDR47 | c.2260C>T p.H754Y (on ENST00000369962 / NM_001142551.2; = p.H755Y on NM_014969.5) | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100728433; called by muse, mutect2
- XDH | c.2461G>A p.G821S | Missense Mutation (SNP) | VAF 72/311 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.813); catalogued as rs765777817, COSV65147788; called by muse, mutect2, varscan2
- ZNF185 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 131/286 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs782551067; called by muse, mutect2, varscan2
- ZNF248 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV61997632; called by muse, mutect2
- ZNF521 | c.3566C>T p.S1189L | Missense Mutation (SNP) | VAF 77/241 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.012); catalogued as rs746089789, COSV64129993; called by muse, mutect2, varscan2
- ZNF728 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 165/349 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV74099494; called by muse, mutect2, varscan2
- AC090517.4 | c.958A>T p.N320Y | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL2 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 90/380 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK2 | c.14278C>T p.P4760S | Missense Mutation (SNP) | VAF 57/346 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ARMCX1 | c.104A>C p.E35A | Missense Mutation (SNP) | VAF 114/378 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ATP10A | c.2561A>C p.N854T | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- B4GALNT1 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 140/413 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- B4GALNT2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 232/401 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- C1QL4 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 46/583 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); called by muse, mutect2
- C5orf34 | c.1751A>G p.Q584R | Missense Mutation (SNP) | VAF 63/345 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC141 | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CCDC168 | c.18880G>T p.D6294Y | Missense Mutation (SNP) | VAF 83/349 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CD163L1 | c.3817G>C p.D1273H | Missense Mutation (SNP) | VAF 16/612 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDH11 | c.1161T>A p.S387R | Missense Mutation (SNP) | VAF 115/456 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTN3 | c.1723T>C p.Y575H | Missense Mutation (SNP) | VAF 101/184 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRB1 | c.1615A>C p.S539R | Missense Mutation (SNP) | VAF 107/460 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CTNND2 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 89/547 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- CYBRD1 | c.558G>C p.L186= | Splice Region (SNP) | VAF 48/227 reads (21%) | called by muse, mutect2, varscan2
- DOCK8 | c.4518C>A p.D1506E | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by muse, mutect2
- EPHB6 | c.170A>C p.D57A | Missense Mutation (SNP) | VAF 113/475 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- FCGR3B | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 61/418 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FZD2 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 145/696 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- GHR | c.1290T>A p.N430K | Missense Mutation (SNP) | VAF 161/432 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- GMIP | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 507/1043 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- GORAB | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 92/388 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); called by muse, mutect2
- GPR150 | c.466G>C p.G156R | Missense Mutation (SNP) | VAF 115/245 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- GRIK2 | c.1505T>G p.V502G | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GRTP1 | c.152A>T p.Q51L | Missense Mutation (SNP) | VAF 84/378 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by mutect2, varscan2
- GUCY1A2 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 205/569 reads (36%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNMA1 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 18/588 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2
- KIAA0825 | c.3041T>G p.L1014R | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRI1 | c.518A>G p.D173G | Missense Mutation (SNP) | VAF 128/711 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- MBL2 | c.401T>G p.V134G | Missense Mutation (SNP) | VAF 89/332 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- MMRN2 | c.1125G>C p.Q375H | Missense Mutation (SNP) | VAF 23/664 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); called by muse, mutect2
- MTHFSD | c.350A>G p.Q117R (on ENST00000360900 / NM_001159377.2; = p.Q116R on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH10 | c.3041A>G p.Q1014R | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYSM1 | c.119C>A p.S40* | Nonsense Mutation (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- NCKAP5 | c.3838A>G p.T1280A | Missense Mutation (SNP) | VAF 35/446 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- NELL1 | c.2113A>C p.S705R | Missense Mutation (SNP) | VAF 88/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR5L2 | c.800G>C p.S267T | Missense Mutation (SNP) | VAF 112/284 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR7A17 | c.503_505del p.F168del | In Frame Del (DEL) | VAF 71/493 reads (14%) | called by mutect2, pindel, varscan2
- OR9H1P | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 13/397 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAX1 | c.5A>C p.K2T | Missense Mutation (SNP) | VAF 106/505 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- PIP5KL1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- PITRM1 | c.35_36del p.V12Afs*19 | Frame Shift Del (DEL) | VAF 130/551 reads (24%) | called by pindel, varscan2
- PKHD1 | c.660C>G p.D220E | Missense Mutation (SNP) | VAF 71/324 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLCL2 | c.3122G>A p.S1041N (on ENST00000615277 / NM_001144382.2; = p.S915N on NM_015184.5) | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- PLSCR4 | c.604T>A p.C202S | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLE | c.4647del p.K1550Nfs*12 | Frame Shift Del (DEL) | VAF 132/622 reads (21%) | called by mutect2, pindel, varscan2
- RIMBP2 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 260/552 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR1 | c.13228G>T p.E4410* | Nonsense Mutation (SNP) | VAF 220/1139 reads (19%) | called by muse, mutect2, varscan2
- RYR2 | c.473G>C p.C158S | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- SEMA4B | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 44/682 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2
- SIAH1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC1A6 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 126/759 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAC | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- STXBP4 | c.766T>G p.F256V | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNM | c.1282_1283del p.F428Lfs*11 | Frame Shift Del (DEL) | VAF 96/692 reads (14%) | called by pindel, varscan2
- SYT16 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 148/328 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- TASOR | c.2883A>C p.L961F (on ENST00000355628 / NM_001365636.2; = p.L585F on NM_015224.3) | Missense Mutation (SNP) | VAF 93/189 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TDRD15 | c.4088T>G p.V1363G | Missense Mutation (SNP) | VAF 89/327 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TF | c.1623_1665del p.X541_splice | Splice Site (DEL) | VAF 32/386 reads (8%) | called by mutect2, pindel
- TNKS2 | c.2480C>G p.S827* | Nonsense Mutation (SNP) | VAF 15/562 reads (3%) | called by muse, mutect2
- TRIM8 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 196/724 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- WDR49 | c.743A>C p.K248T (on ENST00000308378 / NM_001366158.1; = p.K589T on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 130/357 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFPM2 | c.832A>T p.R278* | Nonsense Mutation (SNP) | VAF 106/530 reads (20%) | called by muse, mutect2, varscan2
- ZNF180 | c.803_806del p.T268Kfs*42 | Frame Shift Del (DEL) | VAF 62/222 reads (28%) | called by pindel, varscan2
- ZNF35 | c.473del p.K158Rfs*5 | Frame Shift Del (DEL) | VAF 80/504 reads (16%) | called by mutect2, pindel, varscan2
- ZNF44 | c.1868G>A p.C623Y (on ENST00000356109 / NM_001164276.2; = p.C575Y on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 133/683 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- ZNF544 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 143/763 reads (19%) | called by muse, mutect2, varscan2
- ZNF723 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 41/386 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, varscan2
- AMER1 | c.702C>T p.A234= | Silent (SNP) | VAF 171/402 reads (43%) | catalogued as COSV57655459; called by muse, mutect2, varscan2
- ATAD3C | c.12C>T p.D4= | Silent (SNP) | VAF 80/766 reads (10%) | catalogued as rs780611504, COSV66482608; called by muse, mutect2, varscan2
- ATP2A3 | c.1224C>T p.D408= | Silent (SNP) | VAF 143/402 reads (36%) | catalogued as rs750309947; called by muse, mutect2, varscan2
- BPI | c.33C>T p.N11= (on ENST00000262865; = p.N7= on NM_001725.3) | Silent (SNP) | VAF 124/804 reads (15%) | catalogued as rs532589861, COSV53403696; called by muse, mutect2, varscan2
- CDC14A | c.1692C>T p.I564= | Silent (SNP) | VAF 26/646 reads (4%) | called by muse, mutect2
- CHRM5 | c.1491C>T p.L497= | Silent (SNP) | VAF 139/2664 reads (5%) | called by muse, mutect2
- CLCA2 | c.1500A>G p.T500= | Silent (SNP) | VAF 56/206 reads (27%) | catalogued as rs763852595; called by muse, mutect2, varscan2
- DNAH7 | c.1206C>T p.F402= | Silent (SNP) | VAF 27/243 reads (11%) | catalogued as COSV56778585; called by muse, mutect2, varscan2
- EPHA1 | c.771G>A p.V257= | Silent (SNP) | VAF 138/626 reads (22%) | catalogued as rs773220798; called by muse, mutect2, varscan2
- ESPN | c.3717C>T p.D1239= | Silent (SNP) | VAF 147/402 reads (37%) | catalogued as rs1358535669; called by muse, mutect2, varscan2
- EXOC3L2 | c.585G>A p.L195= | Silent (SNP) | VAF 135/397 reads (34%) | called by muse, mutect2, varscan2
- FAAP100 | c.1674G>A p.S558= | Silent (SNP) | VAF 154/478 reads (32%) | catalogued as rs780718403, COSV59886622; called by muse, mutect2, varscan2
- FAM135B | c.1200C>T p.G400= | Silent (SNP) | VAF 83/505 reads (16%) | catalogued as rs372067880, COSV52746739; called by muse, mutect2, varscan2
- FBXL7 | c.1197G>A p.K399= | Silent (SNP) | VAF 51/754 reads (7%) | catalogued as COSV61654062; called by muse, mutect2
- FBXL8 | c.777G>A p.E259= | Silent (SNP) | VAF 46/829 reads (6%) | called by muse, mutect2
- GPRC6A | c.2637A>G p.T879= | Silent (SNP) | VAF 16/462 reads (3%) | called by muse, mutect2
- INA | c.360C>T p.R120= | Silent (SNP) | VAF 148/593 reads (25%) | catalogued as rs1303379865; called by muse, mutect2, varscan2
- KDM1B | c.882C>A p.L294= | Silent (SNP) | VAF 96/311 reads (31%) | catalogued as COSV52813750; called by muse, varscan2
- L3MBTL4 | c.496T>C p.L166= | Silent (SNP) | VAF 55/185 reads (30%) | called by muse, mutect2, varscan2
- LRRC7 | c.1938T>A p.T646= (on ENST00000651989 / NM_001370785.2; = p.T613= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 108/302 reads (36%) | called by muse, mutect2, varscan2
- MAP1S | c.684G>A p.E228= | Silent (SNP) | VAF 301/1361 reads (22%) | catalogued as rs971243104; called by muse, mutect2, varscan2
- MAPK12 | c.705G>A p.L235= | Silent (SNP) | VAF 75/487 reads (15%) | catalogued as rs1255527292; called by muse, mutect2, varscan2
- MARCO | c.342A>G p.Q114= | Silent (SNP) | VAF 102/525 reads (19%) | catalogued as rs1488020033; called by muse, mutect2, varscan2
- MDN1 | c.12846C>T p.G4282= | Silent (SNP) | VAF 38/694 reads (5%) | catalogued as rs374759478; called by muse, mutect2
- METTL17 | c.1314T>G p.P438= | Silent (SNP) | VAF 122/429 reads (28%) | called by muse, mutect2, varscan2
- MUC17 | c.2422T>C p.L808= | Silent (SNP) | VAF 123/497 reads (25%) | catalogued as rs755357712; called by muse, mutect2, varscan2
- MUC19 | c.537T>C p.S179= | Silent (SNP) | VAF 112/314 reads (36%) | called by muse, mutect2, varscan2
- NCOR2 | c.4791C>T p.H1597= | Silent (SNP) | VAF 137/585 reads (23%) | called by muse, mutect2, varscan2
- P2RY2 | c.288C>T p.G96= | Silent (SNP) | VAF 140/387 reads (36%) | called by muse, mutect2, varscan2
- PBXIP1 | c.699C>G p.L233= | Silent (SNP) | VAF 36/480 reads (8%) | catalogued as rs761827688; called by muse, mutect2
- PLA2G4A | c.801C>G p.L267= | Silent (SNP) | VAF 90/360 reads (25%) | called by muse, mutect2, varscan2
- PLEKHG6 | c.1878C>A p.L626= | Silent (SNP) | VAF 97/364 reads (27%) | called by muse, mutect2, varscan2
- PLG | c.1785A>G p.Q595= | Silent (SNP) | VAF 54/246 reads (22%) | catalogued as COSV57517338; called by muse, mutect2, varscan2
- POLE | c.5661G>A p.V1887= | Silent (SNP) | VAF 113/237 reads (48%) | called by muse, mutect2, varscan2
- PRKCQ | c.1275G>C p.T425= | Silent (SNP) | VAF 122/552 reads (22%) | called by muse, mutect2, varscan2
- SIX4 | c.15C>T p.S5= | Silent (SNP) | VAF 230/436 reads (53%) | called by muse, mutect2, varscan2
- SLC17A7 | c.1293G>A p.P431= | Silent (SNP) | VAF 76/225 reads (34%) | catalogued as rs753945868, COSV55546349; called by muse, mutect2, varscan2
- SP3 | c.255C>T p.A85= | Silent (SNP) | VAF 64/261 reads (25%) | called by muse, mutect2, varscan2
- SPHKAP | c.1569A>G p.Q523= | Silent (SNP) | VAF 111/472 reads (24%) | catalogued as COSV60867482; called by muse, mutect2, varscan2
- TRIM54 | c.456C>T p.F152= | Silent (SNP) | VAF 224/466 reads (48%) | catalogued as rs542384959, COSV56082180; called by muse, mutect2, varscan2
- TRPM3 | c.2793G>A p.G931= (on ENST00000357533 / NM_001366142.2; = p.G774= on NM_020952.6) | Silent (SNP) | VAF 91/256 reads (36%) | catalogued as rs865875184; called by muse, mutect2, varscan2
- TTN | c.47082C>T p.R15694= (on ENST00000591111; = p.R8270= on NM_003319.4) | Silent (SNP) | VAF 87/352 reads (25%) | catalogued as rs940135679, COSV59965340; called by muse, mutect2, varscan2
- UBAP1 | c.1479A>G p.E493= | Silent (SNP) | VAF 102/601 reads (17%) | called by muse, mutect2, varscan2
- VSIR | c.879C>T p.D293= | Silent (SNP) | VAF 104/407 reads (26%) | catalogued as rs769960085; called by muse, mutect2, varscan2
- ZNF493 | c.1341T>C p.C447= | Silent (SNP) | VAF 18/528 reads (3%) | called by muse, mutect2
- ZNF723 | c.1347A>G p.K449= | Silent (SNP) | VAF 256/517 reads (50%) | called by muse, mutect2, varscan2
- ZNF808 | c.1302A>G p.K434= | Silent (SNP) | VAF 61/251 reads (24%) | called by muse, mutect2, varscan2
- CCM2 | c.31-10510C>G | Intron (SNP) | VAF 85/375 reads (23%) | called by muse, mutect2, varscan2
- CKLF-CMTM1 | c.-1G>C | 5'UTR (SNP) | VAF 15/433 reads (3%) | catalogued as rs1219941716; called by muse, mutect2
- CXCL12 | c.266+878G>A | Intron (SNP) | VAF 34/394 reads (9%) | called by muse, mutect2
- DAAM2 | c.1954-1065G>A | Intron (SNP) | VAF 87/394 reads (22%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+746G>C | Intron (SNP) | VAF 31/714 reads (4%) | called by muse, mutect2
- KAZN | c.227-36292G>T | Intron (SNP) | VAF 165/346 reads (48%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1223+122G>A | Intron (SNP) | VAF 33/483 reads (7%) | catalogued as rs935143920; called by muse, mutect2
- NIBAN3 | c.1844-1507C>T | Intron (SNP) | VAF 463/737 reads (63%) | catalogued as rs775474454, COSV53111165; called by muse, mutect2, varscan2
- NPAP1L | n.579C>A | RNA (SNP) | VAF 71/318 reads (22%) | called by muse, mutect2, varscan2
- RAB34 | c.-307_-306del | 5'UTR (DEL) | VAF 68/274 reads (25%) | called by pindel, varscan2
